Somatic mutation profile of tumor specimen TARGET-10-PASZEW-09A (aliquot TARGET-10-PASZEW-09A-01D) from TARGET case TARGET-10-PASZEW, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 7.3 years (2,681 days).
Specimen TARGET-10-PASZEW-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 888a6556-c322-4a8d-be41-4761d30ce9f7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PASZEW-10A (Blood Derived Normal), aliquot TARGET-10-PASZEW-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0238d3e8-e633-4444-be02-bae8ba5b8479

The open-access MAF lists 15 somatic variants for this specimen: 9 protein-altering or splice-affecting, 2 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, 3'UTR 2, Silent 2, Splice Site 1, Frame Shift Ins 1, Intron 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DIRAS1 | c.346G>A p.V116M | Missense Mutation (SNP) | VAF 43/102 reads (42%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.692); catalogued as rs1568294824, COSV60216229; called by muse, mutect2, varscan2
- DNAH7 | c.10717-1G>A p.X3573_splice | Splice Site (SNP) | VAF 21/53 reads (40%) | catalogued as rs868490589, COSV56774119; called by muse, mutect2, varscan2
- INSRR | c.3806G>T p.R1269L | Missense Mutation (SNP) | VAF 15/30 reads (50%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV63875209; called by muse, mutect2, varscan2
- NOTCH1 | c.5161G>A p.V1721M | Missense Mutation (SNP) | VAF 45/99 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53039416; called by muse, mutect2, varscan2
- NSD1 | c.6215G>A p.C2072Y | Missense Mutation (SNP) | VAF 34/69 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV61779455; called by muse, mutect2, varscan2
- PCDHGA2 | c.704C>T p.A235V | Missense Mutation (SNP) | VAF 54/111 reads (49%) | SIFT tolerated, low confidence (0.77); PolyPhen benign (0.014); catalogued as COSV53899200; called by muse, mutect2, varscan2
- VIRMA | c.5414G>A p.R1805H | Missense Mutation (SNP) | VAF 42/100 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.725); catalogued as rs755332512, COSV52583272; called by muse, mutect2, varscan2
- NOTCH1 | c.7228_7229insGGCGGGTCAGC p.P2410Rfs*16 | Frame Shift Ins (INS) | VAF 8/29 reads (28%) | called by pindel, varscan2
- PPFIA4 | c.1246C>T p.R416W (on ENST00000447715; = p.R412W on NM_001304331.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/39 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.436); called by muse, mutect2, varscan2
- CFAP69 | c.2535C>T p.N845= | Silent (SNP) | VAF 15/40 reads (38%) | catalogued as rs558288448, COSV60184206; called by muse, mutect2, varscan2
- SCYL3 | c.1083C>T p.I361= | Silent (SNP) | VAF 5/16 reads (31%) | catalogued as rs746294461, COSV63047208; called by muse, mutect2, varscan2
- BSDC1 | c.*212_*213insCTAATCATTT | 3'UTR (INS) | VAF 34/78 reads (44%) | called by mutect2, pindel, varscan2
- IGHV1-45 | chr14:106506995 ins GCC | 3'Flank (INS) | VAF 34/85 reads (40%) | called by mutect2, pindel, varscan2
- MCF2 | c.*48C>A | 3'UTR (SNP) | VAF 22/57 reads (39%) | called by muse, mutect2, varscan2
- NALCN | c.1765-4620G>A | Intron (SNP) | VAF 5/16 reads (31%) | catalogued as rs1178999729; called by muse, mutect2
